Somatic mutation profile of tumor specimen TCGA-BC-A216-01A (aliquot TCGA-BC-A216-01A-11D-A152-10) from TCGA case TCGA-BC-A216, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 62.9 years (22,968 days).
Specimen TCGA-BC-A216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcf16e64-11f6-4fd1-8384-5f372ebb8a3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A216-11A (Solid Tissue Normal), aliquot TCGA-BC-A216-11A-11D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955f6c59-139d-49ab-a967-5b65bffdc050

The open-access MAF lists 71 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, 3'UTR 3, Nonsense Mutation 3, Intron 3, Splice Site 3, In Frame Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 29/43 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.853A>T p.M285L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV53897693; called by muse, mutect2, varscan2
- ADGRL4 | c.637T>A p.L213I | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV66062295; called by muse, mutect2, varscan2
- AKR1C3 | c.577T>C p.C193R | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1554786102, COSV65910679; called by muse, mutect2, varscan2
- AMER1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV57662247; called by muse, mutect2, varscan2
- AMER3 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV58467681; called by muse, mutect2, varscan2
- ARX | c.29G>C p.C10S | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV66875427; called by muse, mutect2, varscan2
- ASXL1 | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs757758145, COSV60110791, COSV60111806; called by muse, mutect2, varscan2
- AUTS2 | c.2405C>T p.S802L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs868207585, COSV61410205; called by muse, mutect2, varscan2
- BCORL1 | c.3880C>T p.H1294Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.421); catalogued as rs1348032239, COSV54398745; called by muse, mutect2, varscan2
- CNTN1 | c.2185-1G>A p.X729_splice | Splice Site (SNP) | VAF 48/107 reads (45%) | catalogued as COSV61636172; called by muse, mutect2, varscan2
- CSMD3 | c.5439T>A p.D1813E (on ENST00000297405 / NM_001363185.1; = p.D1709E on NM_052900.3) | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52211829; called by muse, mutect2, varscan2
- DIDO1 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1210717795, COSV56625694; called by muse, mutect2, varscan2
- DSP | c.5932A>G p.M1978V | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs770077556, COSV65791717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F8 | c.1774A>T p.K592* | Nonsense Mutation (SNP) | VAF 51/123 reads (41%) | catalogued as COSV51464280; called by muse, mutect2, varscan2
- EHHADH | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51630893; called by muse, mutect2, varscan2
- GLT8D2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV62562170; called by muse, mutect2, varscan2
- GRIN2B | c.3953C>G p.A1318G | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV74206404; called by muse, mutect2, varscan2
- H2AC11 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60362252; called by muse, mutect2, varscan2
- HECTD1 | c.4669C>T p.R1557W | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779029675, COSV67947096; called by muse, mutect2, varscan2
- HMGCLL1 | c.836G>C p.C279S | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1259164359, COSV51446417, COSV51447138; called by muse, mutect2, varscan2
- IBSP | c.492A>T p.E164D | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV56896118; called by muse, mutect2, varscan2
- IGF2BP1 | c.818+1G>A p.X273_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as rs1413532884, COSV51732557; called by muse, mutect2, varscan2
- IL17RD | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.005); catalogued as COSV56339302; called by muse, mutect2, varscan2
- ITGA10 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs782338989, COSV65197837; called by muse, mutect2
- KIDINS220 | c.4916T>C p.I1639T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV56754788; called by muse, varscan2
- KMT2B | c.7432C>A p.Q2478K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55820815; called by muse, mutect2, varscan2
- KRTAP9-3 | c.330T>A p.S110R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV68616548; called by muse, varscan2
- MYO18B | c.4702A>G p.K1568E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV59137688; called by muse, mutect2
- NBPF3 | c.1538G>C p.C513S | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV59060189; called by muse, mutect2, varscan2
- NXF3 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV67703221, COSV67704087; called by muse, mutect2, varscan2
- OR2T2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs766007158, COSV61619558; called by muse, mutect2, varscan2
- PLEKHM1 | c.2248A>G p.T750A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101378685; called by muse, mutect2
- POLR1F | c.811T>C p.W271R | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55998815; called by muse, mutect2, varscan2
- PRKDC | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 52/116 reads (45%) | catalogued as COSV58049652; called by muse, varscan2
- RAB18 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63613637; called by muse, mutect2, varscan2
- RBMS2 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs376730098; called by muse, mutect2, varscan2
- RTP1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs372732386; called by muse, mutect2, varscan2
- SEMA5B | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52100862; called by muse, mutect2, varscan2
- SYNE1 | c.14227A>C p.T4743P (on ENST00000367255 / NM_182961.4; = p.T4672P on NM_033071.3) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV55011143; called by muse, mutect2, varscan2
- TGOLN2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV56406476; called by muse, mutect2, varscan2
- TMEM260 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV55100390; called by muse, mutect2, varscan2
- TMEM92 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV55946409; called by muse, mutect2, varscan2
- TOPBP1 | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV53437287; called by muse, mutect2, varscan2
- TP53BP2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs1187041576, COSV59069539; called by muse, mutect2
- ZNF676 | c.274G>C p.E92Q (on ENST00000650058; = p.E60Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs770321404, COSV68093479, COSV68093834; called by muse, mutect2, varscan2
- POLQ | c.7325_7326del p.T2442Nfs*6 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.1584_1586dup p.A529dup | In Frame Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- ZNF277 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDRF1 | c.1827A>G p.L609= (on ENST00000356792 / NM_001202438.2; = p.L575= on NM_015608.2) | Silent (SNP) | VAF 71/203 reads (35%) | catalogued as COSV61764530, COSV61765684; called by muse, mutect2, varscan2
- FBXO2 | c.291G>A p.L97= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- FCGBP | c.11847C>A p.R3949= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- GPR12 | c.984G>A p.A328= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs754587158, COSV67344029; called by muse, mutect2, varscan2
- KLK12 | c.357C>T p.R119= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs371203521; called by muse, mutect2, varscan2
- MFN1 | c.1794C>T p.G598= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV54940273; called by muse, mutect2, varscan2
- MTNR1A | c.705G>A p.R235= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV56155639, COSV56156629; called by muse, mutect2, varscan2
- MYH1 | c.3768A>G p.L1256= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs776455024, COSV56850641; called by muse, mutect2, varscan2
- MYO1E | c.2835T>G p.T945= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as COSV55689286; called by muse, mutect2, varscan2
- PIWIL1 | c.939C>T p.N313= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV55348009; called by muse, mutect2, varscan2
- SERINC2 | c.1341C>A p.L447= (on ENST00000373709 / NM_178865.5; = p.L451= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as COSV65490787; called by muse, mutect2, varscan2
- SLC8A3 | c.1386G>A p.K462= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV63520626; called by muse, mutect2, varscan2
- VPS26B | c.696G>A p.E232= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV55545469; called by muse, mutect2, varscan2
- ZNF208 | c.105G>A p.E35= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs201303510; called by muse, mutect2
- ZNF490 | c.48G>A p.E16= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58481061, COSV58481363; called by muse, mutect2, varscan2
- B3GALT6 | c.*747G>A | 3'UTR (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99767609; called by muse, mutect2, varscan2
- CDCA7 | c.147+574G>A | Intron (SNP) | VAF 54/176 reads (31%) | catalogued as rs771816691, COSV60720062; called by muse, mutect2, varscan2
- EVL | c.352+12059T>G | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100762599; called by muse, mutect2
- GGA3 | c.-11G>A | 5'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs747837812, COSV99821558; called by muse, mutect2, varscan2
- GRIN1 | c.*323G>T | 3'UTR (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100160239; called by muse, mutect2, varscan2
- KAT2B | c.*8del | 3'UTR (DEL) | VAF 8/28 reads (29%) | catalogued as rs750062124; called by mutect2, varscan2
- MAPT | c.220+2500A>G | Intron (SNP) | VAF 16/33 reads (48%) | catalogued as COSV52241705; called by muse, mutect2, varscan2
